Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A2QS, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A2QS-01A (Primary Tumor).

[page 1 of 4]
Patient

Referring Physician:

Ref#:

Patient Location:

Date of Service: Date Received:

Inpatient

Case #:

Room: Bed:

Date Re

Items were attached to this order:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. KIDNEY, LEFT, RADICAL NEPHRECTOMY:

- DEDIFFERENTIATED LIPOSARCOMA.
- ARISES FROM PERINEPHRIC ADIPOSE TISSUE.
- 11.5 CM IN MAXIMUM DIMENSION.
- MARGIN STATUS: NEGATIVE.
- CONTAINED WITHIN GEROTA'S FASCIA.
- 0.005 CM FROM THE FASCIAL SURFACE.
- LYMPHOVASCULAR INVASION: NOT IDENTIFIED.
- ADRENAL GLAND UNINVOLVED BY TUMOR.

Case in Review		

9/3/11

ICD-0-3

dedifferentiated liposarcoma 8858/3

Path: adipose tissue, flank c49.6

CQCF: retroperitoneum c48.0

PATHOLOGIC STAGING SUMMARY:

- Primary tumor: pT2b (deep tumor, 11.5 cm in greatest dimension).
- Regional lymph nodes: pNX (none submitted for evaluation).
- Distant metastasis: pMX.
- Pathologic stage: III.
- Margin status: R0 (contained within Gerota's fascia, 0.005 cm from fascial surface).

COMMENT: This case was forwarded to _____ in consultation. The diagnosis of dedifferentiated liposarcoma is reflective of their interpretation.

Dr. _____ notified of the consultant's diagnosis at approximately _____ on _____

Case #:

Printed:

Phone:

Page 1

This report continues... (FINAL)

[page 2 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol,

Procedure:

Radical nephrectomy.

TUMOR FEATURES:

Tumor site:

Perinephric adipose tissue, associated with left kidney (abuts but does not invade kidney).

Tumor size:

Greatest dimension: 11.5 cm.

Additional dimensions: 9.5 x 7.5 cm.

Macroscopic extent of tumor:

Deep, retroperitoneal.

Histologic type:

Dedifferentiated liposarcoma.

Mitotic rate:

30 per 10 high power fields.

Necrosis:

Present.

Extent:

Approximately 40%.

Histologic grade:

3.

MARGINS:

Distance from closest margin:

RO (NEGATIVE).

Lymphovascular invasion:

0.005 cm from anterior surface of Gerota's fascia.
Not identified.

PATHOLOGIC STAGING:

Primary tumor:

pT2b (deep tumor, 11.5 cm in greatest dimension).

Regional lymph nodes:

pNX.

Distant metastasis:

pMX.

Tumor stage:

III.

Margin status:

RO (closest margin, anterior surface of Gerota's fascia, 0.005 cm).

Pre-resection treatment:

No therapy.

Additional findings:

Chronic interstitial nephritis.
Hyaline arteriolar sclerosis.

MD, Pathologist

Signec

Case #:

Page 2

Printed:

This report continues... (FINAL)

Phone

[page 3 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

A. Left kidney nephrectomy

Clinical History/Operative Dx:

Left renal mass

Gross Description:

A. The specimen is labeled left kidney and is received without fixative. It consists of a nephrectomy specimen which together with perinephric fat weighs 865.0 grams. The specimen measures 19.5 cm from superior to inferior, 11.0 cm from medial to lateral and 8.5 cm from anterior to posterior. Along the medial superior edge of the perinephric fat there is a 4.8 x 2.0 x 0.7 cm portion of adrenal gland. On sectioning the adrenal gland is partially autolyzed and there is a very small 0.2 cm focus of pale tan discoloration of the adrenal cortical tissue centrally. The anterior surface as well as the superior portion of the kidney is bulging and distorted. Over the anterior surface there is a 10.0 x 8.5 cm portion of thin delicate membranous tissue consistent with Gerota's fascia. Gerota's fascia is inked black. At the hilum the renal artery and renal vein are identified. The vessels are opened and there is no gross evidence of intraluminal tumor. Extending from the hilum is a thin and delicate portion of ureter which is 7.0 cm in length and has a maximum diameter of 0.3 cm. The ureter is opened and the urothelium is tan-white, smooth and unremarkable. The kidney is bivalved to reveal an upper pole tumor mass which at its periphery is translucent and tan-white, centrally dull yellow-tan and possibly infarcted. The tumor mass measures 11.5 x 9.5 x 7.5 cm. With gentle manipulation, the tumor mass appears to attach itself to the renal capsule at the superior pole and does not, except for a small focus, appear to be attached to the cortical surface of the kidney. Serial sections of the tumor reveal it is in the perinephric fat and abuts Gerota's fascia along the anterior surface. Tumor approaches to within 0.4 cm of the adrenal gland. Tumor is present at the perirenal fat at the hilum. The uninvolved kidney shows fatty infiltration of the hilum and a well delineated cortical medullary junction. The cortical thickness is 0.6 cm. No other renal parenchymal masses are identified. Dissection of the perinephric fat reveals no obvious lymph nodes. Representative sections are submitted. Sections summary: (A1) surgical margin renal artery, renal vein and ureter, (A2) adrenal gland with possible tumor implant, (A3) sections of tumor and renal capsule adherent to superior pole of kidney, (A4) tumor adherent to cortical surface of superior pole, (A5) tumor abutting Gerota's fascia and tumor and closest approach to adrenal gland, (A6-A7) representative sections of tumor, (A8) tumor and renal pelvic adipose tissue, (A9) uninvolved kidney. (DS)

Microscopic Description:

A. Sections of the kidney tumor show a spindle cell neoplasm, with marked nuclear pleomorphism, nuclear hyperchromasia, scattered multinucleated cells, numerous mitoses, and areas of necrosis. The neoplastic cells are positive for CD34, Vimentin, and focally for smooth muscle actin. The cells are negative for OSCAR keratin, PAX-8, smooth muscle myosin, S100, CD31, CAM5.2, Desmin, Melan-a, HMB45, and muscle specific actin. All staining controls are appropriately reactive.

Case #:

Printed:

Phone:

Fax:

Page 3

This report continues... (FINAL)

[page 4 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

B. See reference lab report.

Case #:

Printed:

Phone:

Page 4

This report continues... (FINAL)

Source: NCI Genomic Data Commons file 885dae1a-ec18-4c66-8991-d6a5aeb3f719 (TCGA-FX-A2QS.55148DBE-D662-4930-8B29-15905F0A459D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).